Somatic mutation profile of tumor specimen TCGA-34-2604-01A (aliquot TCGA-34-2604-01A-01D-1522-08) from TCGA case TCGA-34-2604, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 81.7 years (29,827 days).
Specimen TCGA-34-2604-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d203d8d-d331-4b41-b642-8cfe6da9d734.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-2604-11A (Solid Tissue Normal), aliquot TCGA-34-2604-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ad1748f-da1f-497c-85a1-54bfe36317ef

The open-access MAF lists 622 somatic variants for this specimen: 474 protein-altering or splice-affecting, 130 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 409, Silent 130, Nonsense Mutation 28, Splice Site 20, Intron 10, Frame Shift Del 10, RNA 6, Splice Region 4, Frame Shift Ins 2, In Frame Ins 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 24/101 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- ABCA10 | c.4337A>T p.Q1446L | Missense Mutation (SNP) | VAF 84/209 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV99289158; called by muse, mutect2, varscan2
- ABCA9 | c.2767+1G>T p.X923_splice | Splice Site (SNP) | VAF 156/426 reads (37%) | catalogued as COSV100383370; called by muse, mutect2, varscan2
- AC098582.1 | c.361A>T p.T121S | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99985891; called by muse, mutect2, varscan2
- ACSL3 | c.1414G>T p.G472C | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV100658057; called by muse, mutect2, varscan2
- ACTL9 | c.1025G>A p.G342D | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100185495; called by muse, mutect2, varscan2
- ACVRL1 | c.1247G>A p.G416D | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV101188072; called by muse, mutect2
- ADAM19 | c.1099G>T p.D367Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57422648; called by muse, mutect2, varscan2
- ADAM2 | c.875C>G p.A292G | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs746985909, COSV99697743; called by muse, mutect2
- ADAM33 | c.1388G>A p.C463Y | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1378161696, COSV100598013; called by muse, mutect2, varscan2
- ADAM9 | c.2076T>G p.N692K | Missense Mutation (SNP) | VAF 41/478 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV101166223; called by muse, mutect2
- ADARB1 | c.1807C>T p.R603W (on ENST00000360697 / NM_001346687.2; = p.R563W on NM_001112.4) | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100654052; called by muse, mutect2, varscan2
- ADCY8 | c.2783T>A p.L928H | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99653670; called by muse, mutect2
- ADGRA2 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs144591273; called by muse, varscan2
- ADGRA3 | c.2066C>A p.T689K | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99293679; called by muse, mutect2, varscan2
- ADGRV1 | c.11581G>T p.D3861Y | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1311978141, COSV101315645, COSV101316332; called by muse, mutect2, varscan2
- AK7 | c.1180C>G p.H394D | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99967473; called by muse, mutect2
- AKR7L | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV101334288, COSV101334372; called by muse, mutect2, varscan2
- ALOX15B | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV101205689; called by muse, mutect2, varscan2
- ALS2 | c.4864C>T p.H1622Y | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as COSV99969875; called by muse, mutect2, varscan2
- AMDHD2 | c.788T>C p.F263S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99566078; called by muse, mutect2, varscan2
- AMY2A | c.605T>C p.I202T | Missense Mutation (SNP) | VAF 66/976 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV70214824; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.2286T>G p.D762E | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.05); catalogued as COSV99784108; called by muse, mutect2, varscan2
- ANKS1B | c.1740G>C p.E580D | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1397783827, COSV100247276; called by muse, mutect2
- ANO10 | c.593-2A>G p.X198_splice | Splice Site (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99428857; called by muse, mutect2, varscan2
- ANO3 | c.2729T>G p.L910R | Missense Mutation (SNP) | VAF 94/356 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99884865; called by muse, mutect2, varscan2
- ANXA3 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 74/369 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99363890; called by muse, varscan2
- APBA1 | c.1805A>T p.Q602L | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99596881; called by muse, mutect2, varscan2
- ARHGEF19 | c.568G>T p.G190C | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV99580690; called by muse, mutect2, varscan2
- ARMH4 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV99958759; called by muse, mutect2
- ARVCF | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV99599456; called by muse, mutect2
- ASB11 | c.224A>G p.Q75R | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as rs1031381638, COSV100729112; called by muse, mutect2, varscan2
- ASB5 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.822); catalogued as COSV99641996; called by muse, mutect2, varscan2
- ASIC5 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs745353708, COSV101611163, COSV73332867; called by muse, mutect2, varscan2
- ASPRV1 | c.908G>T p.C303F | Missense Mutation (SNP) | VAF 102/412 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100208601; called by muse, mutect2, varscan2
- ASTN1 | c.3545A>T p.D1182V | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100707577; called by muse, mutect2, varscan2
- ATP10A | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100791431; called by muse, mutect2, varscan2
- ATP11A | c.2926G>C p.A976P | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV99369648; called by muse, mutect2, varscan2
- ATP6V1E1 | c.277-1G>T p.X93_splice | Splice Site (SNP) | VAF 40/303 reads (13%) | catalogued as COSV99494417; called by muse, mutect2
- ATP8A1 | c.3025A>G p.I1009V | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100047033; called by muse, mutect2, varscan2
- ATRNL1 | c.1055C>A p.P352H | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as COSV100746724; called by muse, mutect2, varscan2
- BFSP2 | c.716G>T p.R239I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV100183873; called by muse, mutect2, varscan2
- BTBD7 | c.2221G>C p.A741P | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as COSV100598102; called by muse, mutect2, varscan2
- C14orf28 | c.929A>C p.K310T | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100290331; called by muse, mutect2, varscan2
- C3AR1 | c.955A>C p.N319H | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as COSV99368845; called by muse, mutect2, varscan2
- C4BPA | c.1322G>A p.S441N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.093); catalogued as rs779478751, COSV100891272; called by muse, mutect2, varscan2
- C6 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99667590; called by muse, mutect2, varscan2
- C6orf118 | c.1394G>A p.R465K | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.013); catalogued as COSV100024879, COSV100024951, COSV57813264; called by muse, mutect2, varscan2
- C8B | c.1652G>A p.W551* | Nonsense Mutation (SNP) | VAF 9/128 reads (7%) | catalogued as COSV100980862; called by muse, mutect2
- CACNA1B | c.627G>T p.L209F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99499029; called by muse, mutect2, varscan2
- CACNA1G | c.4422G>A p.Q1474= | Splice Region (SNP) | VAF 46/138 reads (33%) | catalogued as COSV100662338; called by muse, mutect2, varscan2
- CACNG7 | c.706G>C p.A236P | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV99712225; called by muse, mutect2, varscan2
- CBLL2 | c.578T>A p.V193E | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.172); catalogued as COSV100081700; called by muse, mutect2, varscan2
- CCDC58 | c.51G>A p.Q17= | Splice Region (SNP) | VAF 29/135 reads (21%) | catalogued as COSV99216443; called by muse, mutect2, varscan2
- CCDC88C | c.1514A>T p.Q505L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV101106032; called by muse, mutect2, varscan2
- CCN2 | c.949A>G p.M317V | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.994); catalogued as rs752118942, COSV100915318, COSV100915349; called by muse, mutect2, varscan2
- CCR8 | c.878G>A p.C293Y | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100413152; called by muse, mutect2, varscan2
- CD163L1 | c.2373C>A p.A791= | Splice Region (SNP) | VAF 20/82 reads (24%) | catalogued as COSV100550539; called by muse, mutect2, varscan2
- CD1A | c.972C>A p.R324= | Splice Region (SNP) | VAF 44/346 reads (13%) | catalogued as COSV99192555; called by muse, mutect2, varscan2
- CD36 | c.31G>C p.A11P | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV59209648, COSV99987784; called by muse, mutect2, varscan2
- CDC73 | c.1456G>T p.D486Y | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100813948; called by muse, mutect2
- CDCA7 | c.470G>T p.R157M (on ENST00000347703 / NM_145810.3; = p.R236M on NM_031942.5) | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV100143708; called by muse, mutect2, varscan2
- CDH19 | c.631A>G p.K211E | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV100050631, COSV100052056; called by muse, mutect2, varscan2
- CDH23 | c.5166C>A p.H1722Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99823086; called by muse, mutect2
- CENPE | c.7180A>G p.K2394E | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV99478800; called by muse, mutect2
- CEP170 | c.4220G>T p.S1407I | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100317632; called by muse, mutect2, varscan2
- CEP43 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV100835713, COSV62761283; called by muse, mutect2, varscan2
- CFAP36 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100171111; called by muse, mutect2, varscan2
- CFAP47 | c.1835C>A p.P612Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV99935641; called by muse, mutect2, varscan2
- CFAP47 | c.5255T>C p.L1752S | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100545623; called by muse, mutect2, varscan2
- CFAP61 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 76/438 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs371793125, COSV55639118; called by muse, varscan2
- CFAP61 | c.3059C>A p.P1020H | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99846165; called by muse, mutect2, varscan2
- CFHR2 | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV100804377; called by muse, mutect2, varscan2
- CGNL1 | c.517A>G p.N173D | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV99848919; called by muse, mutect2, varscan2
- CHD6 | c.3287A>C p.E1096A | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100498571; called by muse, mutect2, varscan2
- CHL1 | c.2138G>C p.R713T (on ENST00000397491 / NM_001253387.1; = p.R729T on NM_006614.4) | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs757916934, COSV99852005; called by muse, mutect2, varscan2
- CHMP7 | c.532G>T p.V178L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.057); catalogued as COSV100500715; called by muse, mutect2, varscan2
- CHPF | c.1197G>T p.E399D | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99705212; called by muse, mutect2, varscan2
- CHRNA1 | c.826C>A p.L276M (on ENST00000261007 / NM_001039523.3; = p.L251M on NM_000079.4) | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99650634; called by muse, mutect2, varscan2
- CLIC4 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100978202; called by muse, mutect2, varscan2
- CMYA5 | c.6820G>T p.D2274Y | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); catalogued as COSV71404665; called by muse, mutect2, varscan2
- CNTRL | c.2947G>T p.V983L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.919); catalogued as COSV53047316, COSV99443367; called by muse, mutect2, varscan2
- COBLL1 | c.883G>T p.A295S (on ENST00000392717; = p.A257S on NM_014900.5) | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52063980; called by muse, mutect2, varscan2
- COL11A2 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100554398; called by muse, mutect2, varscan2
- COL12A1 | c.4028T>G p.L1343* | Nonsense Mutation (SNP) | VAF 29/235 reads (12%) | catalogued as COSV100486346; called by muse, mutect2, varscan2
- COL19A1 | c.2677G>T p.G893C | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100507137; called by muse, mutect2
- COL4A4 | c.1297G>T p.G433* | Nonsense Mutation (SNP) | VAF 27/133 reads (20%) | catalogued as COSV100307462, COSV61629784; called by muse, mutect2, varscan2
- CR1 | c.4148C>T p.P1383L | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100887960; called by muse, mutect2, varscan2
- CRAT | c.50A>T p.K17M | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV100534167; called by muse, mutect2, varscan2
- CREBRF | c.377C>G p.P126R | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99756245; called by muse, mutect2
- CRYBG3 | c.6529G>C p.D2177H | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51709468, COSV99477338; called by muse, mutect2, varscan2
- CSMD3 | c.6115G>T p.G2039* (on ENST00000297405 / NM_001363185.1; = p.G1935* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 37/229 reads (16%) | catalogued as COSV99828407; called by muse, mutect2, varscan2
- CUL2 | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101039256; called by muse, mutect2, varscan2
- CWH43 | c.1866-1G>C p.X622_splice | Splice Site (SNP) | VAF 15/174 reads (9%) | catalogued as COSV99893830; called by muse, mutect2
- CYLD | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 78/321 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV100282676; called by muse, mutect2, varscan2
- CYP8B1 | c.900G>T p.K300N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100296249; called by muse, mutect2, varscan2
- DACT3 | c.1808T>G p.V603G | Missense Mutation (SNP) | VAF 107/510 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100340470; called by muse, varscan2
- DDX20 | c.2377C>A p.H793N | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100862328; called by muse, mutect2, varscan2
- DEUP1 | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV99977485; called by muse, mutect2, varscan2
- DGKB | c.2362A>G p.T788A | Missense Mutation (SNP) | VAF 27/268 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99342353; called by muse, mutect2
- DLL4 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs1249351611, COSV99989949; called by muse, mutect2
- DNAH11 | c.5589C>A p.S1863R | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV100180263; called by muse, mutect2, varscan2
- DNAH5 | c.12771C>A p.D4257E | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200349959, COSV54233919; called by muse, mutect2, varscan2
- DNAH7 | c.7632A>T p.L2544F | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267599138, COSV100416861; called by muse, mutect2, varscan2
- DNAH7 | c.483C>G p.I161M | Missense Mutation (SNP) | VAF 67/362 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.08); catalogued as rs777242244, COSV100416862; called by muse, mutect2, varscan2
- DNAH8 | c.11025C>G p.N3675K | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100546729; called by muse, mutect2, varscan2
- DNAH9 | c.5788G>T p.E1930* | Nonsense Mutation (SNP) | VAF 15/76 reads (20%) | catalogued as COSV99307421; called by muse, mutect2, varscan2
- DNAI3 | c.2465A>T p.E822V | Missense Mutation (SNP) | VAF 75/304 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV99642276; called by muse, mutect2, varscan2
- DNAJC13 | c.620G>C p.R207P | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.071); catalogued as COSV99607853; called by muse, mutect2, varscan2
- DRD3 | c.1006+1G>A p.X336_splice | Splice Site (SNP) | VAF 26/144 reads (18%) | catalogued as COSV99879625; called by muse, mutect2, varscan2
- DRGX | c.88C>G p.R30G | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV100938379; called by muse, mutect2, varscan2
- DYM | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.802); catalogued as COSV99493849; called by muse, mutect2, varscan2
- DYSF | c.5857C>T p.P1953S | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.04); catalogued as rs751990869, COSV99249772; called by muse, mutect2
- DZIP3 | c.2249G>T p.R750M | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV100847984; called by muse, mutect2, varscan2
- EBF1 | c.254A>G p.E85G | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58198399; called by muse, mutect2, varscan2
- EIF2B1 | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57459760, COSV99967639; called by muse, mutect2, varscan2
- EPHX2 | c.185A>T p.Q62L | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV100994742; called by muse, mutect2, varscan2
- EPS15L1 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1380654722, COSV99933215, COSV99933532; called by muse, varscan2
- ESRRG | c.590-1G>A p.X197_splice | Splice Site (SNP) | VAF 18/146 reads (12%) | catalogued as COSV63148166; called by muse, mutect2
- F8 | c.6325C>A p.R2109S | Missense Mutation (SNP) | VAF 104/368 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.4); catalogued as CM001998, COSV100811770, COSV100811958; called by muse, varscan2
- FAM170A | c.825C>A p.S275R | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.238); catalogued as COSV100089243; called by muse, mutect2, varscan2
- FANCM | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 16/136 reads (12%) | catalogued as COSV99361110; called by muse, mutect2, varscan2
- FAT1 | c.10855G>T p.G3619W | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499574; called by muse, mutect2, varscan2
- FFAR1 | c.333del p.L112Wfs*103 | Frame Shift Del (DEL) | VAF 21/90 reads (23%) | catalogued as COSV50051596; called by pindel, varscan2
- FFAR1 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs772248176, COSV99323641; called by muse, varscan2
- FGD3 | c.610A>T p.I204F | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100490790; called by muse, mutect2, varscan2
- FGF10 | c.326G>T p.S109I | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99240888; called by muse, mutect2, varscan2
- FLNA | c.4678G>T p.V1560L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV100775028; called by muse, varscan2
- FLNC | c.3235A>C p.T1079P | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV100368577; called by muse, varscan2
- FMN2 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as COSV100146758; called by muse, mutect2
- FOXB2 | c.799A>T p.K267* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100942377; called by muse, mutect2, varscan2
- FPR3 | c.633C>G p.S211R | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV100200839, COSV59331090; called by muse, mutect2, varscan2
- FSTL5 | c.2281A>T p.S761C | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as COSV100059617; called by muse, mutect2, varscan2
- FUT5 | c.121G>C p.A41P | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99398932; called by muse, mutect2, varscan2
- GAB4 | c.471A>C p.E157D | Missense Mutation (SNP) | VAF 161/626 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV101272076; called by muse, mutect2, varscan2
- GABRB2 | c.584A>G p.D195G | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99196429; called by muse, mutect2, varscan2
- GALNT17 | c.973A>C p.M325L | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.048); catalogued as COSV100355480; called by muse, mutect2, varscan2
- GBA3 | c.607A>G p.R203G | Missense Mutation (SNP) | VAF 76/334 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as rs1427487267, COSV101545546; called by muse, mutect2, varscan2
- GLMN | c.791G>T p.R264M | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.151); catalogued as COSV100950149; called by muse, mutect2, varscan2
- GLMP | c.509G>C p.S170T | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.541); catalogued as COSV99828054; called by muse, mutect2, varscan2
- GLRX5 | c.333A>T p.Q111H | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100495926; called by muse, mutect2, varscan2
- GORAB | c.1022A>T p.Q341L | Missense Mutation (SNP) | VAF 43/283 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV100883859; called by muse, mutect2, varscan2
- GOT1L1 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100294654; called by muse, mutect2
- GPR149 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 92/291 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV101078658, COSV67670597; called by muse, mutect2, varscan2
- GPR158 | c.2845G>T p.D949Y | Missense Mutation (SNP) | VAF 46/277 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs138563761, COSV66265206; called by muse, mutect2, varscan2
- GPR50 | c.1758C>G p.D586E | Missense Mutation (SNP) | VAF 39/269 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV99506469; called by muse, mutect2, varscan2
- GPRC6A | c.2158A>T p.T720S | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.527); catalogued as COSV100114634; called by muse, mutect2, varscan2
- GPX5 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 78/336 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101297280; called by muse, mutect2, varscan2
- GRM1 | c.2204C>A p.S735Y | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV99268314; called by muse, mutect2, varscan2
- GRM7 | c.1986G>T p.L662F | Missense Mutation (SNP) | VAF 58/257 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100737925; called by muse, mutect2, varscan2
- GSK3B | c.992C>T p.P331L (on ENST00000264235 / NM_001146156.2; = p.P344L on NM_002093.4) | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99955368; called by muse, varscan2
- GSK3B | c.937G>C p.A313P (on ENST00000264235 / NM_001146156.2; = p.A326P on NM_002093.4) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99955371; called by muse, varscan2
- GUCY1A1 | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.926); catalogued as COSV99638347, COSV99639023; called by muse, mutect2
- HDGF | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100625878; called by muse, mutect2, varscan2
- HEATR5B | c.3301G>T p.V1101L | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99250031; called by muse, mutect2, varscan2
- HELZ2 | c.7030G>C p.A2344P (on ENST00000467148 / NM_001037335.2; = p.A1775P on NM_033405.3) | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100918809, COSV100918828; called by muse, mutect2, varscan2
- HMCN1 | c.14126G>T p.W4709L | Missense Mutation (SNP) | VAF 68/334 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99633989; called by muse, mutect2, varscan2
- HTATIP2 | c.138A>T p.K46N | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV101346180; called by muse, mutect2
- IFI44L | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 22/251 reads (9%) | catalogued as COSV100655065; called by muse, mutect2
- IGDCC3 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100031432; called by muse, varscan2
- IGHV1-46 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as rs782115511; called by muse, mutect2, varscan2
- IGHV3-72 | c.163T>A p.W55R | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV101455375; called by muse, mutect2, varscan2
- IMP4 | c.270_271insT p.R91Sfs*30 | Frame Shift Ins (INS) | VAF 8/62 reads (13%) | catalogued as COSV99383824; called by mutect2, pindel, varscan2
- IQCC | c.254A>T p.N85I | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV99356762; called by muse, mutect2
- IRF6 | c.1081G>T p.G361* | Nonsense Mutation (SNP) | VAF 15/122 reads (12%) | catalogued as COSV100884020; called by muse, mutect2, varscan2
- ITGA2B | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 101/233 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.284); catalogued as COSV99289156; called by muse, mutect2, varscan2
- ITPRID1 | c.827C>A p.S276Y | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100087218, COSV60072072; called by muse, mutect2, varscan2
- JUN | c.44A>T p.N15I | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.522); catalogued as COSV100973474; called by muse, mutect2, varscan2
- KCNC3 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs377078916; called by muse, mutect2, varscan2
- KCNH5 | c.1258G>T p.V420L | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV100526701; called by muse, mutect2
- KCNJ9 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927790; called by muse, mutect2
- KCNK10 | c.597G>T p.L199F | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV100069045, COSV56646944; called by muse, mutect2, varscan2
- KCNK3 | c.738C>A p.F246L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV100257084; called by muse, varscan2
- KCNK9 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271511; called by muse, mutect2, varscan2
- KCNT1 | c.3238C>T p.R1080W (on ENST00000488444; = p.R1106W on NM_020822.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs542409033, COSV99706461; called by muse, varscan2
- KDM3A | c.1823A>C p.K608T | Missense Mutation (SNP) | VAF 93/350 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as COSV100460830, COSV57225080; called by muse, mutect2, varscan2
- KERA | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 73/320 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.102); catalogued as rs1387243299, COSV99899526; called by muse, mutect2, varscan2
- KIAA1549 | c.1300G>T p.A434S | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99651668; called by muse, mutect2, varscan2
- KIF2B | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV52132386, COSV52136561; called by muse, mutect2
- KLHL4 | c.419C>A p.A140E | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV64139230; called by muse, mutect2, varscan2
- KMO | c.714C>A p.F238L | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100844714; called by muse, mutect2, varscan2
- KPNA3 | c.723G>T p.Q241H | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV99904323; called by muse, varscan2
- KRT6C | c.1218G>C p.Q406H | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99360149; called by muse, mutect2, varscan2
- KRTAP10-9 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV100554998; called by muse, mutect2, varscan2
- KRTAP11-1 | c.353C>A p.S118Y | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60095258; called by muse, mutect2, varscan2
- KYNU | c.955+1G>T p.X319_splice | Splice Site (SNP) | VAF 35/160 reads (22%) | catalogued as COSV99933796; called by muse, mutect2, varscan2
- LARS1 | c.2671G>T p.V891F (on ENST00000394434 / NM_020117.11; = p.V864F on NM_016460.3) | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs754663860, COSV50976312, COSV99198733; called by muse, mutect2, varscan2
- LCOR | c.3775G>T p.A1259S | Missense Mutation (SNP) | VAF 60/278 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as COSV99617091; called by muse, mutect2, varscan2
- LILRB5 | c.655+1G>T p.X219_splice | Splice Site (SNP) | VAF 25/145 reads (17%) | catalogued as rs1569062130, COSV100300690; called by muse, mutect2, varscan2
- LINGO1 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs1200453719, COSV62436222; called by muse, mutect2, varscan2
- LINGO4 | c.1434C>A p.D478E | Missense Mutation (SNP) | VAF 68/336 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100765023; called by muse, varscan2
- LNX1 | c.928G>T p.G310W (on ENST00000263925 / NM_001126328.3; = p.G214W on NM_032622.2) | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99820385; called by muse, mutect2, varscan2
- LPIN3 | c.1942A>T p.T648S | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100182764; called by muse, mutect2, varscan2
- LRFN5 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99985010; called by muse, mutect2, varscan2
- LRFN5 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV53261940, COSV99985012; called by muse, mutect2, varscan2
- LRP10 | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100612461; called by muse, mutect2, varscan2
- LRP1B | c.6955C>A p.H2319N | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101259476, COSV67223213; called by muse, mutect2, varscan2
- LRP1B | c.1544C>A p.S515* | Nonsense Mutation (SNP) | VAF 31/135 reads (23%) | catalogued as rs1558829171, COSV67200346; called by muse, mutect2, varscan2
- LRRC30 | c.194A>T p.D65V | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV101274443; called by muse, mutect2, varscan2
- LRRC40 | c.1065+1G>T p.X355_splice | Splice Site (SNP) | VAF 4/49 reads (8%) | catalogued as COSV100918834; called by muse, mutect2
- LRRC66 | c.1706G>T p.S569I | Missense Mutation (SNP) | VAF 64/255 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100603052; called by muse, mutect2, varscan2
- LRRC7 | c.1312G>A p.D438N (on ENST00000651989 / NM_001370785.2; = p.D405N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99228928, COSV99230791; called by muse, mutect2, varscan2
- LRRC8A | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.894); catalogued as COSV99396843; called by muse, mutect2, varscan2
- LTBP3 | c.2431T>C p.C811R | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99534465; called by muse, mutect2, varscan2
- LYPD6B | c.107G>C p.W36S (on ENST00000409029 / NM_001317004.1; = p.W60S on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/449 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV99700429; called by muse, mutect2, varscan2
- MAGEC3 | c.749A>C p.Y250S | Missense Mutation (SNP) | VAF 55/371 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV100025923, COSV53580124; called by muse, mutect2, varscan2
- MAP2 | c.4906A>T p.I1636F | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as COSV52288139, COSV99561327; called by muse, mutect2, varscan2
- MAP3K19 | c.3411C>A p.S1137R | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100209063, COSV59641438; called by muse, mutect2, varscan2
- MAP3K19 | c.2414C>A p.S805* | Nonsense Mutation (SNP) | VAF 24/226 reads (11%) | catalogued as COSV100209064, COSV100209511, COSV59638494; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1403G>T p.R468L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV53798101, COSV99571685; called by muse, mutect2, varscan2
- MARCO | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.32); catalogued as rs1400383392, COSV59055668; called by muse, mutect2, varscan2
- MBOAT2 | c.1358A>C p.H453P | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100020519; called by muse, mutect2, varscan2
- MBOAT2 | c.1357C>A p.H453N | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1226877825, COSV100020521; called by muse, mutect2, varscan2
- MCM4 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100031787; called by muse, mutect2, varscan2
- MEPE | c.1328T>A p.L443H | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV100734981; called by muse, mutect2, varscan2
- MERTK | c.2726G>T p.R909L | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as CM066130, COSV99775118; called by muse, mutect2, varscan2
- MIB2 | c.2066C>T p.A689V | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as rs377728128; called by muse, mutect2, varscan2
- MME | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 122/313 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1005427481, COSV100852497; called by muse, varscan2
- MME | c.358+2T>C p.X120_splice | Splice Site (SNP) | VAF 96/256 reads (38%) | catalogued as COSV100852498; called by muse, varscan2
- MPEG1 | c.728C>A p.A243D | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as COSV99915861; called by muse, mutect2, varscan2
- MRPL58 | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.215); catalogued as COSV100043037; called by muse, mutect2, varscan2
- MS4A14 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 66/214 reads (31%) | catalogued as COSV100280664; called by muse, mutect2, varscan2
- MSH4 | c.2293A>T p.T765S | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99592287; called by muse, mutect2, varscan2
- MTOR | c.6088G>A p.G2030S | Missense Mutation (SNP) | VAF 63/508 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV100816565; called by muse, mutect2, varscan2
- MUC16 | c.23736A>T p.L7912F | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.12); catalogued as COSV101200849; called by muse, mutect2, varscan2
- MUC16 | c.13673G>A p.S4558N | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV101200850; called by muse, mutect2, varscan2
- MUC17 | c.4895T>C p.L1632P | Missense Mutation (SNP) | VAF 133/527 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs768593476, COSV100074637; called by muse, mutect2, varscan2
- MUC4 | c.16136G>T p.G5379V (on ENST00000463781 / NM_018406.7; = p.G1143V on NM_004532.6) | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100206001; called by muse, mutect2, varscan2
- MYBPC3 | c.2503C>T p.R835C | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs765356720, COSV99920857; called by muse, mutect2, varscan2
- MYCBP2 | c.6376A>C p.N2126H (on ENST00000357337; = p.N2164H on NM_015057.5) | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as rs558360189, COSV100631380; called by muse, mutect2, varscan2
- MYH14 | c.1984C>T p.P662S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV99223694; called by muse, mutect2, varscan2
- MYH4 | c.3919C>G p.R1307G | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99701952; called by muse, mutect2, varscan2
- MYH8 | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs200421774, COSV67973440; called by muse, mutect2, varscan2
- MYL1 | c.18C>G p.D6E | Missense Mutation (SNP) | VAF 54/432 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100751687, COSV100751700; called by muse, varscan2
- MYO15A | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV99234004; called by muse, mutect2, varscan2
- MYO7B | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748812090, COSV67347950; called by muse, mutect2, varscan2
- MYO7B | c.1941C>A p.C647* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV101267952; called by muse, mutect2, varscan2
- NAA11 | c.30C>A p.D10E | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99727539; called by muse, mutect2, varscan2
- NAV3 | c.4442-2A>T p.X1481_splice | Splice Site (SNP) | VAF 10/88 reads (11%) | catalogued as rs753494158, COSV99894278; called by muse, mutect2
- NCAM2 | c.338-1G>C p.X113_splice | Splice Site (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99524666, COSV99525897; called by muse, mutect2, varscan2
- NCAN | c.1933C>A p.P645T | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV99388035; called by muse, mutect2, varscan2
- NCR1 | c.505G>T p.G169W | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52557489; called by muse, mutect2, varscan2
- NF1 | c.6427+1del | Frame Shift Del (DEL) | VAF 31/140 reads (22%) | catalogued as CM1313756; called by mutect2, pindel, varscan2
- NHS | c.2819G>T p.R940I | Missense Mutation (SNP) | VAF 39/259 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101196893; called by muse, mutect2, varscan2
- NISCH | c.665_666insCTC p.V222_E223insS | In Frame Ins (INS) | VAF 13/76 reads (17%) | catalogued as COSV100617603; called by mutect2, pindel, varscan2
- NLN | c.574A>G p.K192E | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV101114428; called by muse, mutect2, varscan2
- NLRP5 | c.2583A>T p.L861F | Missense Mutation (SNP) | VAF 88/529 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101173833; called by muse, mutect2, varscan2
- NOTCH4 | c.3039G>T p.Q1013H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV100900904; called by muse, mutect2, varscan2
- NPC1 | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99341774; called by muse, mutect2, varscan2
- NPHS1 | c.2261G>T p.G754V | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62286552; called by muse, mutect2, varscan2
- NPHS1 | c.2260G>T p.G754W | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546810048, COSV100800181; called by muse, mutect2, varscan2
- NPNT | c.1653A>T p.L551F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99975369; called by muse, mutect2, varscan2
- NR3C2 | c.797G>T p.S266I | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV100679622; called by muse, mutect2, varscan2
- NRCAM | c.2639G>A p.G880D (on ENST00000379028 / NM_001371124.1; = p.G864D on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100695249; called by muse, mutect2, varscan2
- OLFML2A | c.1898G>A p.R633Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs377560457; called by muse, mutect2, varscan2
- OPN5 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 109/372 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99789986; called by muse, mutect2, varscan2
- OR10A7 | c.469A>G p.M157V | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs934340032, COSV58277807; called by muse, mutect2, varscan2
- OR10G9 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 62/260 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100901714; called by muse, mutect2
- OR1B1 | c.611C>A p.A204D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100506520, COSV59171265; called by muse, mutect2, varscan2
- OR2D2 | c.381C>A p.C127* | Nonsense Mutation (SNP) | VAF 54/189 reads (29%) | catalogued as rs775862453, COSV100203904; called by muse, mutect2, varscan2
- OR2F1 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 129/521 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231325; called by muse, mutect2, varscan2
- OR2L2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 123/576 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs142994715, COSV63549338; called by muse, mutect2, varscan2
- OR2L2 | c.592G>T p.V198L | Missense Mutation (SNP) | VAF 98/490 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.162); catalogued as COSV100824253; called by muse, mutect2, varscan2
- OR2T34 | c.362C>A p.A121D | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100170487; called by muse, varscan2
- OR2W3 | c.120del p.G41Afs*94 | Frame Shift Del (DEL) | VAF 46/265 reads (17%) | catalogued as COSV100831654, COSV100831783; called by mutect2, pindel*, varscan2
- OR4D6 | c.168C>G p.H56Q | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.196); catalogued as COSV100271796; called by muse, mutect2, varscan2
- OR4Q3 | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100057209, COSV100057282; called by muse, mutect2, varscan2
- OR51A7 | c.198G>T p.L66F | Missense Mutation (SNP) | VAF 89/298 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1049660650, COSV100834730; called by muse, mutect2, varscan2
- OR51I2 | c.185T>A p.F62Y | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV100413449; called by muse, mutect2, varscan2
- OR52E8 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 93/300 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as rs551753112, COSV101190402, COSV66207529; called by muse, mutect2, varscan2
- OR5P3 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.06); catalogued as COSV100103243; called by muse, mutect2, varscan2
- OR6C3 | c.726G>C p.M242I | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.042); catalogued as rs745974102, COSV101110378; called by muse, mutect2, varscan2
- OR6C74 | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV59606924, COSV59607419; called by muse, mutect2, varscan2
- OR6F1 | c.567C>A p.C189* | Nonsense Mutation (SNP) | VAF 18/217 reads (8%) | catalogued as COSV100129392; called by muse, mutect2
- OR8G1 | c.37A>C p.I13L | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as COSV100422581; called by muse, mutect2, varscan2
- OR9A2 | c.310G>T p.G104W | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100628279; called by muse, mutect2, varscan2
- OR9Q2 | c.368A>T p.Y123F | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.769); catalogued as COSV100285501; called by muse, mutect2, varscan2
- P2RX6 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100298826; called by muse, mutect2, varscan2
- PADI1 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs774174409, COSV100968559; called by muse, mutect2, varscan2
- PALB2 | c.3201+1G>A p.X1067_splice | Splice Site (SNP) | VAF 15/83 reads (18%) | catalogued as CS122634, COSV99848864; called by muse, mutect2, varscan2
- PASD1 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV100949531, COSV100949696; called by muse, varscan2
- PCDH11X | c.3006G>T p.E1002D | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100014184; called by muse, mutect2, varscan2
- PCDH15 | c.4928C>A p.S1643Y | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious, low confidence (0); catalogued as COSV100905375; called by muse, mutect2, varscan2
- PCDH18 | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100787456; called by muse, mutect2, varscan2
- PCDHA7 | c.286T>A p.C96S | Missense Mutation (SNP) | VAF 46/364 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100971709; called by muse, mutect2, varscan2
- PCDHB1 | c.1109C>T p.T370I | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV100128336; called by muse, mutect2, varscan2
- PCDHGA6 | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.106); catalogued as COSV99544203; called by muse, mutect2, varscan2
- PCLO | c.11815C>T p.Q3939* | Nonsense Mutation (SNP) | VAF 93/775 reads (12%) | catalogued as COSV100436264; called by muse, mutect2, varscan2
- PCLO | c.5662A>G p.T1888A | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV100436267; called by muse, mutect2, varscan2
- PCNX3 | c.5204G>A p.R1735H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs775172031, COSV63136601; called by muse, mutect2, varscan2
- PCSK6 | c.983A>G p.Y328C | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.863); catalogued as rs1031984432, COSV100083939; called by muse, mutect2
- PDCL | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV52342381, COSV99414207; called by muse, mutect2, varscan2
- PEG3 | c.3386A>G p.H1129R | Missense Mutation (SNP) | VAF 55/332 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); catalogued as COSV99690015; called by muse, mutect2, varscan2
- PEX5L | c.605G>C p.R202T | Missense Mutation (SNP) | VAF 121/353 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); catalogued as COSV55849678; called by muse, mutect2, varscan2
- PHLPP1 | c.4189G>T p.A1397S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV99408956; called by muse, mutect2, varscan2
- PKD2 | c.2542C>T p.R848W | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99418015; called by muse, mutect2
- PKHD1L1 | c.2595G>T p.Q865H | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV101006662; called by muse, mutect2
- PKHD1L1 | c.2728G>T p.V910F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV101006663; called by muse, mutect2, varscan2
- PLAGL2 | c.772G>T p.G258C | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99867475; called by muse, mutect2, varscan2
- PLXND1 | c.5323A>C p.I1775L | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100140271; called by muse, mutect2, varscan2
- PM20D1 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs142439282, COSV65649184; called by muse, mutect2, varscan2
- PNLIP | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.923); catalogued as COSV100981933; called by muse, mutect2
- POM121L12 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.159); catalogued as COSV101374960, COSV68693781; called by muse, mutect2, varscan2
- POSTN | c.1163T>A p.V388E | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV101123453; called by muse, mutect2, varscan2
- PPM1K | c.59G>T p.R20I | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV99901113; called by muse, mutect2, varscan2
- PRAME | c.1013A>T p.D338V | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101287207; called by muse, mutect2, varscan2
- PRCP | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 75/235 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV100476285; called by muse, mutect2, varscan2
- PRKAB2 | c.274A>T p.I92F | Missense Mutation (SNP) | VAF 46/446 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV99568040; called by muse, mutect2, varscan2
- PROKR2 | c.8C>A p.A3D | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs758128077, COSV99450541; called by muse, mutect2, varscan2
- PROM1 | c.1108A>T p.R370* | Nonsense Mutation (SNP) | VAF 45/211 reads (21%) | catalogued as COSV101477121; called by muse, mutect2, varscan2
- PRSS35 | c.788G>T p.W263L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV100864131; called by muse, mutect2, varscan2
- PSKH1 | c.883A>G p.M295V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.261); catalogued as rs1374332593, COSV99344935; called by muse, mutect2, varscan2
- PTCHD3 | c.1790C>G p.T597R | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV101438953, COSV71257323; called by muse, mutect2, varscan2
- RABL3 | c.267T>A p.N89K | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as COSV99846620; called by muse, mutect2, varscan2
- RASSF2 | c.683C>A p.T228K | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV101040888; called by muse, mutect2, varscan2
- RBFA | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100080284; called by muse, mutect2, varscan2
- RBM25 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99998947; called by muse, mutect2
- RBP3 | c.3586C>T p.R1196C | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs267602496; called by muse, varscan2
- RC3H1 | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV99281664; called by muse, mutect2
- REST | c.809A>G p.H270R | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100471252; called by muse, mutect2, varscan2
- RFPL2 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.051); catalogued as COSV99964493; called by muse, mutect2, varscan2
- RFPL4B | c.183G>T p.L61F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV101480721, COSV71437687; called by muse, mutect2, varscan2
- RIOK3 | c.958A>T p.N320Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100259428; called by muse, mutect2, varscan2
- RIPK4 | c.131G>C p.W44S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100205277; called by muse, mutect2, varscan2
- RNASE11 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 61/411 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV100250597, COSV60087657; called by muse, mutect2, varscan2
- RNF40 | c.1781C>A p.P594H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.441); catalogued as COSV100222277; called by muse, mutect2, varscan2
- ROBO1 | c.4675G>T p.D1559Y | Missense Mutation (SNP) | VAF 228/1036 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV101459144; called by muse, mutect2, varscan2
- RPGRIP1 | c.739A>T p.K247* | Nonsense Mutation (SNP) | VAF 13/93 reads (14%) | catalogued as COSV99251598; called by muse, mutect2, varscan2
- RUNDC3B | c.673A>T p.I225F | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.105); catalogued as COSV100407209; called by muse, mutect2
- RUNDC3B | c.1006C>A p.L336M | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.688); catalogued as COSV100407212; called by muse, mutect2
- RYR1 | c.5011G>T p.A1671S | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.4); catalogued as COSV100616636, COSV62110536; called by muse, mutect2, varscan2
- RYR2 | c.5376A>G p.I1792M | Missense Mutation (SNP) | VAF 78/326 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV100772168; called by mutect2, varscan2
- RYR3 | c.3258G>T p.K1086N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV101213759; called by muse, mutect2, varscan2
- SALL4 | c.1010A>C p.Q337P | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99409535, COSV99409779; called by muse, mutect2, varscan2
- SCARB2 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as rs773957659, COSV53667672; called by muse, mutect2, varscan2
- SCN2A | c.1843C>A p.H615N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV99332981; called by muse, varscan2
- SCN7A | c.1990T>A p.C664S | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV69268054; called by mutect2, varscan2
- SCNN1B | c.7G>C p.V3L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV100225539, COSV100225883; called by muse, mutect2, varscan2
- SEMA3D | c.38G>T p.S13I | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as COSV99407196; called by muse, mutect2
- SEMA4F | c.1374G>T p.E458D | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV100336108; called by muse, mutect2, varscan2
- SEMA6B | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100015056; called by muse, mutect2, varscan2
- SERINC3 | c.570G>C p.W190C | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV99667935; called by muse, mutect2, varscan2
- SERPINA11 | c.449G>C p.R150P | Missense Mutation (SNP) | VAF 32/396 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.665); catalogued as COSV100593918, COSV100594176; called by muse, mutect2
- SETD5 | c.4183G>C p.G1395R | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV100200987, COSV100201001; called by muse, mutect2, varscan2
- SETX | c.5626A>T p.N1876Y | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV99810604; called by muse, mutect2, varscan2
- SGIP1 | c.1550C>A p.A517E | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99392498; called by muse, mutect2, varscan2
- SI | c.4087C>A p.P1363T | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100016718, COSV52292312; called by muse, mutect2
- SIK3 | c.1330G>T p.E444* (on ENST00000445177 / NM_001366686.2; = p.E450* on NM_025164.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | catalogued as COSV99408614; called by muse, mutect2, varscan2
- SIPA1L3 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs756536229, COSV99730054; called by muse, mutect2, varscan2
- SLC12A2 | c.3074A>C p.D1025A | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99321435; called by muse, mutect2, varscan2
- SLC17A6 | c.971G>T p.W324L | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99582094; called by muse, mutect2, varscan2
- SLC22A16 | c.1539G>A p.M513I | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV100397827; called by muse, mutect2, varscan2
- SLC30A3 | c.616A>T p.S206C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99273816; called by muse, mutect2, varscan2
- SLC38A5 | c.706G>T p.V236L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV100476702; called by muse, varscan2
- SLC6A17 | c.1033G>T p.V345L | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.612); catalogued as COSV100521468; called by muse, mutect2, varscan2
- SLC9C2 | c.2164-1G>T p.X722_splice | Splice Site (SNP) | VAF 14/130 reads (11%) | catalogued as rs779235280, COSV100876943; called by muse, mutect2, varscan2
- SMYD1 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1205453259, COSV101352493; called by muse, mutect2, varscan2
- SND1 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100690917; called by muse, mutect2
- SNED1 | c.2852C>A p.S951Y | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as COSV100123235; called by muse, mutect2, varscan2
- SPAG17 | c.4498A>G p.T1500A | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1379404512, COSV100310118; called by muse, mutect2, varscan2
- SPAG17 | c.1246+1G>T p.X416_splice | Splice Site (SNP) | VAF 88/492 reads (18%) | catalogued as COSV100310122; called by muse, mutect2, varscan2
- SPATA31D1 | c.3023C>A p.T1008N | Missense Mutation (SNP) | VAF 88/362 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs767994748, COSV100782988; called by muse, mutect2, varscan2
- SPRED2 | c.419G>C p.G140A | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.526); catalogued as COSV100710302; called by muse, mutect2
- SPTA1 | c.3376G>T p.D1126Y | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935382, COSV63750078; called by muse, mutect2, varscan2
- SPTBN1 | c.3794G>T p.S1265I | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1310128998, COSV100443219; called by muse, varscan2
- SPTLC3 | c.1132G>T p.G378C | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100983251; called by muse, mutect2, varscan2
- STC2 | c.698A>G p.K233R | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV99438588; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2811G>T p.L937F | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as COSV100561931; called by muse, mutect2, varscan2
- STRC | c.4067G>C p.C1356S | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101348021; called by muse, mutect2, varscan2
- STRIP2 | c.2389G>T p.V797L | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.232); catalogued as COSV50803582, COSV99974070; called by muse, mutect2, varscan2
- SUCLA2 | c.955G>T p.D319Y (on ENST00000643023; = p.D298Y on NM_003850.3) | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101074922; called by muse, mutect2, varscan2
- SVIL | c.2567C>A p.T856K (on ENST00000355867 / NM_021738.3; = p.T430K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100881467; called by muse, varscan2
- SYCP1 | c.2853G>A p.M951I | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101051110; called by muse, mutect2, varscan2
- SYNE1 | c.15972C>A p.D5324E (on ENST00000367255 / NM_182961.4; = p.D5253E on NM_033071.3) | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99574904; called by muse, mutect2
- SYNE1 | c.5101-2A>C p.X1701_splice (on ENST00000367255 / NM_182961.4; = p.X1708_splice on NM_033071.3) | Splice Site (SNP) | VAF 18/135 reads (13%) | catalogued as COSV99574909; called by muse, mutect2, varscan2
- SYS1 | c.218A>T p.N73I | Missense Mutation (SNP) | VAF 114/708 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99713965; called by muse, mutect2, varscan2
- SYT14 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 22/116 reads (19%) | catalogued as COSV99655874; called by muse, varscan2
- TACC2 | c.5601G>T p.Q1867H (on ENST00000334433; = p.Q58H on NM_206861.3) | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV100553407; called by muse, mutect2, varscan2
- TAF1L | c.4972C>A p.P1658T | Missense Mutation (SNP) | VAF 123/421 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.293); catalogued as COSV99644189; called by muse, mutect2, varscan2
- TAS2R14 | c.629A>G p.K210R | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.233); catalogued as rs780814771, COSV101115355; called by muse, mutect2, varscan2
- TBX20 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV101282405, COSV68783067; called by muse, mutect2, varscan2
- TBX5 | c.810C>A p.N270K | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV100091871; called by muse, mutect2, varscan2
- TFCP2 | c.93G>C p.Q31H | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs748065303, COSV99227796; called by muse, mutect2, varscan2
- THSD7A | c.4384C>A p.Q1462K | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101448845; called by muse, mutect2, varscan2
- TINAG | c.968C>A p.A323E | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.383); catalogued as COSV99450491; called by muse, mutect2
- TINAGL1 | c.764C>A p.S255* | Nonsense Mutation (SNP) | VAF 25/126 reads (20%) | catalogued as COSV54700139, COSV99593046; called by muse, mutect2, varscan2
- TLX1 | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as COSV100930095, COSV100930113; called by muse, mutect2, varscan2
- TMEM154 | c.364+1G>T p.X122_splice | Splice Site (SNP) | VAF 31/299 reads (10%) | catalogued as COSV100433188; called by muse, mutect2, varscan2
- TMEM200C | c.253G>T p.G85W | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs763098598, COSV101274858, COSV67309485; called by muse, mutect2, varscan2
- TMEM237 | c.346G>T p.A116S (on ENST00000409883 / NM_001044385.3; = p.A108S on NM_152388.4) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.023); catalogued as COSV99636160; called by muse, mutect2
- TMPRSS15 | c.1987G>T p.D663Y | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99518900; called by muse, mutect2, varscan2
- TMSB4X | c.39C>G p.F13L | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV101020331, COSV101020361; called by muse, mutect2, varscan2
- TNFRSF13C | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV99351787; called by muse, mutect2, varscan2
- TNN | c.1736G>T p.G579V | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV99512698; called by muse, varscan2
- TNN | c.3380G>T p.R1127M | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53437472, COSV99512700; called by muse, mutect2, varscan2
- TRAF5 | c.790-1G>A p.X264_splice | Splice Site (SNP) | VAF 21/202 reads (10%) | catalogued as COSV99807557; called by muse, mutect2, varscan2
- TRHDE | c.473T>A p.M158K | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV99671979; called by muse, mutect2
- TRHDE | c.474G>T p.M158I | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV99671980; called by muse, mutect2
- TRMT1L | c.1393G>C p.V465L | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV100834711; called by muse, mutect2
- TRPC3 | c.908C>A p.S303Y (on ENST00000379645 / NM_001366479.2; = p.S230Y on NM_003305.2) | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99313303; called by muse, mutect2
- TRRAP | c.7671G>T p.E2557D (on ENST00000359863 / NM_001244580.1; = p.E2539D on NM_003496.3) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.046); catalogued as COSV100722790; called by muse, mutect2, varscan2
- TSPAN2 | c.70C>A p.L24M | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101050046; called by muse, mutect2
- TSPOAP1 | c.4367A>T p.E1456V | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99272244; called by muse, mutect2, varscan2
- TTC21B | c.3145G>T p.A1049S | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV99692706; called by muse, mutect2
- TTF2 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV101037756; called by muse, mutect2, varscan2
- TTK | c.2246A>T p.D749V | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100036527; called by muse, mutect2
- TTLL2 | c.784G>C p.V262L | Missense Mutation (SNP) | VAF 50/413 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99514921; called by muse, mutect2, varscan2
- TTLL5 | c.2050C>T p.L684F | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1032611319, COSV100091257; called by muse, mutect2, varscan2
- TTN | c.87029C>T p.P29010L (on ENST00000591111; = p.P21586L on NM_003319.4) | Missense Mutation (SNP) | VAF 34/169 reads (20%) | PolyPhen benign (0.003); catalogued as COSV59906301; called by muse, mutect2, varscan2
- TTN | c.56753A>G p.Q18918R (on ENST00000591111; = p.Q11494R on NM_003319.4) | Missense Mutation (SNP) | VAF 26/160 reads (16%) | PolyPhen benign (0.415); catalogued as COSV100624724; called by muse, mutect2, varscan2
- TTN | c.23225C>T p.A7742V (on ENST00000591111; = p.A6815V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/154 reads (24%) | PolyPhen possibly damaging (0.592); catalogued as rs1301357470, COSV100624733; called by muse, mutect2, varscan2
- TTN | c.9302A>G p.D3101G (on ENST00000591111; = p.D3055G on NM_003319.4) | Missense Mutation (SNP) | VAF 48/199 reads (24%) | PolyPhen benign (0.367); catalogued as COSV100624741; called by muse, mutect2, varscan2
- TXLNB | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100625128; called by muse, mutect2, varscan2
- UBE2F | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99800410; called by muse, mutect2
- UNC13C | c.6252T>A p.F2084L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99521717; called by muse, mutect2, varscan2
- UNC5B | c.1295-2A>C p.X432_splice | Splice Site (SNP) | VAF 11/94 reads (12%) | catalogued as COSV100101168; called by muse, mutect2, varscan2
- UNC5D | c.1743G>T p.M581I | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV99777816; called by muse, mutect2, varscan2
- UNC79 | c.7787G>A p.G2596D (on ENST00000393151 / NM_001346218.2; = p.G2419D on NM_020818.5) | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.961); catalogued as COSV56407802, COSV99829415; called by muse, mutect2, varscan2
- USF3 | c.4585C>A p.Q1529K | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV100324918, COSV100325661; called by muse, mutect2, varscan2
- USH2A | c.11128G>T p.G3710C | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100240248; called by muse, varscan2
- USH2A | c.6893C>T p.P2298L | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100240256; called by muse, mutect2, varscan2
- USP29 | c.536C>A p.T179K | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99518467; called by muse, mutect2, varscan2
- USP7 | c.2737G>A p.D913N | Missense Mutation (SNP) | VAF 111/589 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100784356; called by muse, mutect2, varscan2
- UTS2B | c.325A>T p.S109C | Missense Mutation (SNP) | VAF 42/518 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV100484330; called by muse, mutect2
- VEPH1 | c.310C>G p.P104A | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100747897; called by muse, mutect2, varscan2
- VPS35L | c.1783A>T p.K595* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as COSV99221490; called by muse, mutect2, varscan2
- VPS53 | c.597G>T p.Q199H (on ENST00000571805 / NM_001366253.2; = p.Q170H on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV99346545; called by muse, varscan2
- VRTN | c.171A>T p.E57D | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV99832419; called by muse, mutect2, varscan2
- VSX1 | c.899G>C p.G300A | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100942197; called by muse, varscan2
- WDR17 | c.1737G>C p.E579D | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV99708079; called by muse, mutect2, varscan2
- WDR17 | c.3220-1G>T p.X1074_splice | Splice Site (SNP) | VAF 13/99 reads (13%) | catalogued as COSV99708080; called by muse, mutect2, varscan2
- WSCD2 | c.78C>G p.Y26* | Nonsense Mutation (SNP) | VAF 26/308 reads (8%) | catalogued as COSV99775071; called by muse, mutect2
- XAGE3 | c.86C>A p.P29H | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as COSV100655693; called by muse, mutect2, varscan2
- XK | c.687T>A p.F229L | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV101064769; called by muse, mutect2, varscan2
- XPO4 | c.1798A>T p.R600* | Nonsense Mutation (SNP) | VAF 44/217 reads (20%) | catalogued as COSV99689046; called by muse, mutect2, varscan2
- ZBTB21 | c.2335G>T p.E779* | Nonsense Mutation (SNP) | VAF 101/438 reads (23%) | catalogued as COSV100177320, COSV60403814; called by muse, mutect2, varscan2
- ZBTB41 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100963379; called by muse, mutect2, varscan2
- ZFHX3 | c.1639A>T p.T547S | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV99214185; called by muse, mutect2
- ZFHX4 | c.4419C>A p.S1473R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs540974936, COSV50478898, COSV99266312; called by muse, mutect2, varscan2
- ZIC1 | c.1334G>A p.W445* | Nonsense Mutation (SNP) | VAF 39/189 reads (21%) | catalogued as COSV51555085, COSV99292262; called by muse, mutect2, varscan2
- ZNF107 | c.464C>G p.T155S | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as COSV100788464; called by muse, mutect2, varscan2
- ZNF154 | c.540G>C p.W180C | Missense Mutation (SNP) | VAF 89/460 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as rs777280887, COSV101377538, COSV70744932; called by muse, mutect2
- ZNF211 | c.1345G>T p.G449W (on ENST00000347302 / NM_198855.4; = p.G462W on NM_006385.5) | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1405457836, COSV99560425; called by muse, mutect2, varscan2
- ZNF23 | c.1351A>G p.N451D | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs754893318, COSV100612238; called by muse, mutect2, varscan2
- ZNF250 | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs1225378328, COSV52968208, COSV52969065; called by muse, mutect2, varscan2
- ZNF292 | c.1760A>G p.H587R | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100370928; called by muse, mutect2, varscan2
- ZNF37A | c.1417G>T p.G473W | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61074492; called by muse, mutect2, varscan2
- ZNF385D | c.833C>G p.S278W | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99875930; called by muse, mutect2, varscan2
- ZNF408 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 64/319 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100305606; called by muse, mutect2, varscan2
- ZNF536 | c.1886A>T p.K629M | Missense Mutation (SNP) | VAF 48/339 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100835650; called by muse, mutect2, varscan2
- ZNF606 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 71/407 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.816); catalogued as COSV100357488; called by muse, mutect2, varscan2
- ZNF611 | c.583A>G p.R195G | Missense Mutation (SNP) | VAF 95/429 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV100160521; called by muse, mutect2, varscan2
- ZNF804A | c.925C>G p.P309A | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV100169559; called by muse, mutect2, varscan2
- ZNF827 | c.601A>T p.T201S | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV101061636; called by muse, mutect2, varscan2
- ZNF98 | c.1637A>G p.Y546C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1421558244, COSV63335121, COSV63337942; called by muse, mutect2, varscan2
- ZNFX1 | c.3977T>A p.I1326N | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV100872542; called by muse, mutect2, varscan2
- ZZEF1 | c.6739G>A p.V2247M | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779969346, COSV101067960; called by muse, mutect2, varscan2
- ARVCF | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2
- BRD7 | c.666del p.K223Sfs*7 | Frame Shift Del (DEL) | VAF 64/262 reads (24%) | called by mutect2, varscan2
- CLEC4E | c.414del p.F138Lfs*21 | Frame Shift Del (DEL) | VAF 28/137 reads (20%) | called by mutect2, pindel, varscan2
- GAS2L2 | c.1586C>A p.T529K | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- IGKV1D-42 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 44/366 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, varscan2
- ITGA8 | c.3126del p.R1043Dfs*7 | Frame Shift Del (DEL) | VAF 17/103 reads (17%) | called by pindel, varscan2
- LAMA2 | c.9297del p.K3099Nfs*13 | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | called by mutect2, pindel
- LRRN2 | c.1871C>A p.A624D | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- MINDY4 | c.1293del p.W431* | Frame Shift Del (DEL) | VAF 26/155 reads (17%) | called by mutect2, pindel, varscan2
- MLF1 | c.404del p.G135Efs*3 | Frame Shift Del (DEL) | VAF 22/228 reads (10%) | called by mutect2, pindel
- MROH2B | c.539dup p.N180Kfs*5 | Frame Shift Ins (INS) | VAF 44/272 reads (16%) | called by mutect2, pindel, varscan2
- PRAMEF10 | c.423G>T p.M141I | Missense Mutation (SNP) | VAF 52/761 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2
- TMEM236 | c.458G>T p.R153I | Missense Mutation (SNP) | VAF 102/577 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- TRAV1-1 | c.103G>T p.V35F | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2
- TTN | c.32707G>T p.A10903S (on ENST00000591111; = p.A9976S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | PolyPhen benign (0.13); called by muse, mutect2
- ZNF37A | c.321del p.K107Nfs*4 | Frame Shift Del (DEL) | VAF 24/222 reads (11%) | called by mutect2, varscan2
- ZNF488 | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABI3 | c.489A>T p.T163= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV99865758; called by muse, mutect2
- ADCY5 | c.870C>T p.R290= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101518453; called by muse, mutect2
- AKAP9 | c.9219G>T p.L3073= (on ENST00000359028; = p.L3049= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 111/544 reads (20%) | catalogued as COSV100662875; called by muse, mutect2, varscan2
- APAF1 | c.586C>T p.L196= (on ENST00000551964 / NM_181861.2; = p.L185= on NM_001160.3) | Silent (SNP) | VAF 96/322 reads (30%) | catalogued as COSV100244355; called by muse, mutect2, varscan2
- APOB | c.13428A>T p.I4476= | Silent (SNP) | VAF 92/357 reads (26%) | catalogued as COSV99267213; called by muse, mutect2, varscan2
- ASIC5 | c.369C>A p.A123= | Silent (SNP) | VAF 13/146 reads (9%) | catalogued as COSV101539785; called by muse, mutect2
- ASXL1 | c.1326G>C p.V442= | Silent (SNP) | VAF 43/226 reads (19%) | catalogued as COSV100037555, COSV100040722; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2106G>T p.L702= | Silent (SNP) | VAF 53/178 reads (30%) | catalogued as COSV100377113; called by muse, mutect2, varscan2
- BEND5 | c.858G>T p.A286= | Silent (SNP) | VAF 24/293 reads (8%) | catalogued as COSV100884166; called by muse, mutect2
- BMP10 | c.210C>T p.D70= | Silent (SNP) | VAF 37/285 reads (13%) | catalogued as COSV99770555; called by muse, mutect2, varscan2
- C18orf25 | c.48C>T p.S16= | Silent (SNP) | VAF 15/121 reads (12%) | catalogued as rs374873414; called by muse, mutect2, varscan2
- C3orf70 | c.378T>A p.I126= | Silent (SNP) | VAF 154/367 reads (42%) | catalogued as COSV100621322; called by muse, mutect2, varscan2
- CCDC102B | c.1144A>C p.R382= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV100104415; called by muse, mutect2
- CDA | c.378C>G p.V126= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100906377; called by muse, mutect2, varscan2
- CDH10 | c.1401C>A p.P467= | Silent (SNP) | VAF 39/207 reads (19%) | catalogued as COSV100052678; called by muse, mutect2, varscan2
- CEP290 | c.7023T>G p.L2341= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV100469472; called by muse, mutect2, varscan2
- CFAP91 | c.2106G>T p.L702= | Silent (SNP) | VAF 28/150 reads (19%) | catalogued as COSV99847401; called by muse, mutect2, varscan2
- CHIA | c.1362C>A p.V454= (on ENST00000343320; = p.V346= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV100588803; called by muse, mutect2, varscan2
- CHML | c.78A>G p.A26= | Silent (SNP) | VAF 37/312 reads (12%) | catalogued as COSV100087692; called by muse, mutect2, varscan2
- CHRM2 | c.672T>A p.P224= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV100281710; called by muse, mutect2, varscan2
- CIDEA | c.282A>T p.G94= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as rs150815921, COSV100255303; called by muse, mutect2, varscan2
- CNTNAP2 | c.411C>A p.P137= | Silent (SNP) | VAF 22/210 reads (10%) | catalogued as COSV62217057; called by muse, mutect2, varscan2
- CORIN | c.3027C>A p.V1009= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as COSV99904217; called by muse, mutect2, varscan2
- CRABP1 | c.180C>G p.R60= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100211289; called by muse, mutect2, varscan2
- CYP17A1 | c.1095C>T p.P365= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as rs759770054, COSV100882131; called by muse, mutect2, varscan2
- EMILIN2 | c.1128G>C p.L376= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as rs1321949084, COSV99598798, COSV99599003; called by muse, mutect2
- EML5 | c.927G>C p.V309= | Silent (SNP) | VAF 27/202 reads (13%) | catalogued as COSV100716079; called by muse, mutect2, varscan2
- ERCC3 | c.993G>A p.G331= | Silent (SNP) | VAF 141/876 reads (16%) | catalogued as rs148629399; called by muse, mutect2, varscan2
- FAM135B | c.339G>T p.V113= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV99357895; called by muse, mutect2, varscan2
- FAM71B | c.318C>A p.A106= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as COSV100262255; called by muse, mutect2, varscan2
- FASLG | c.399C>T p.H133= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs1049754208, COSV100390597; called by muse, mutect2, varscan2
- FAT4 | c.12099C>A p.A4033= | Silent (SNP) | VAF 32/195 reads (16%) | catalogued as rs774481338, COSV100629701, COSV58673897; called by muse, mutect2, varscan2
- FCAR | c.582C>T p.Y194= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs749038112, COSV62028254; called by muse, mutect2, varscan2
- FCRL3 | c.660A>T p.P220= | Silent (SNP) | VAF 28/163 reads (17%) | catalogued as COSV100943470; called by muse, mutect2, varscan2
- GAPVD1 | c.3588T>C p.C1196= (on ENST00000394104; = p.C1205= on NM_015635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/249 reads (26%) | catalogued as rs867478093, COSV52924737; called by muse, mutect2, varscan2
- GCSAML | c.225C>T p.I75= | Silent (SNP) | VAF 49/255 reads (19%) | catalogued as COSV63577526; called by muse, mutect2, varscan2
- GPR139 | c.342C>A p.T114= | Silent (SNP) | VAF 43/180 reads (24%) | catalogued as COSV100429972, COSV100429983; called by muse, mutect2, varscan2
- GPR4 | c.60G>T p.P20= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as rs760707691, COSV100547170; called by muse, mutect2, varscan2
- GPR6 | c.372C>A p.G124= | Silent (SNP) | VAF 26/236 reads (11%) | catalogued as COSV99254477; called by muse, mutect2, varscan2
- GPR65 | c.444C>A p.V148= | Silent (SNP) | VAF 46/427 reads (11%) | catalogued as COSV99966133; called by muse, mutect2, varscan2
- GRM3 | c.570C>A p.T190= | Silent (SNP) | VAF 24/256 reads (9%) | catalogued as rs754123274, COSV64469532, COSV64473417; called by muse, mutect2
- HHIPL2 | c.553C>T p.L185= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as rs753325195, COSV100597029; called by muse, mutect2, varscan2
- HOXC10 | c.90C>G p.G30= | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as COSV100329144; called by muse, mutect2, varscan2
- HRG | c.18A>G p.A6= | Silent (SNP) | VAF 23/191 reads (12%) | catalogued as COSV99214987; called by muse, mutect2, varscan2
- HTR1E | c.1029C>A p.L343= | Silent (SNP) | VAF 25/214 reads (12%) | catalogued as COSV100541235; called by muse, mutect2, varscan2
- HTR4 | c.66G>A p.L22= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs201439456, COSV58796745; called by muse, mutect2, varscan2
- ICE1 | c.5769A>C p.A1923= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99665411; called by muse, mutect2, varscan2
- IFIT1 | c.537T>A p.A179= | Silent (SNP) | VAF 35/411 reads (9%) | catalogued as COSV100878760; called by muse, mutect2
- IGHV1-18 | c.102G>T p.G34= | Silent (SNP) | VAF 34/216 reads (16%) | catalogued as rs781952536; called by muse, mutect2, varscan2
- IGSF22 | c.2623C>A p.R875= (on ENST00000319338; = p.R976= on NM_173588.4) | Silent (SNP) | VAF 47/175 reads (27%) | catalogued as COSV55011821, COSV99773831; called by muse, mutect2, varscan2
- INHBC | c.336T>A p.T112= | Silent (SNP) | VAF 64/562 reads (11%) | catalogued as COSV100548039; called by muse, mutect2, varscan2
- INPP5B | c.2781C>T p.H927= (on ENST00000373023; = p.H847= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as COSV100886579; called by muse, mutect2
- JPH2 | c.48G>C p.G16= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as rs917953744, COSV100652615; called by muse, mutect2, varscan2
- KCNK9 | c.705C>T p.I235= | Silent (SNP) | VAF 19/139 reads (14%) | catalogued as rs747620541, COSV57281660; called by muse, mutect2, varscan2
- KLK6 | c.492C>A p.S164= | Silent (SNP) | VAF 21/133 reads (16%) | catalogued as COSV100037810; called by muse, mutect2, varscan2
- KMO | c.681T>A p.P227= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as COSV100844713; called by muse, mutect2
- LOXL1 | c.1383C>T p.Y461= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs748019800, COSV56094560; called by muse, mutect2, varscan2
- LRGUK | c.150G>A p.T50= | Silent (SNP) | VAF 36/161 reads (22%) | catalogued as rs1323093580, COSV99603715, COSV99604561; called by muse, mutect2, varscan2
- LRP2 | c.7347C>A p.A2449= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as COSV99789798; called by muse, mutect2, varscan2
- MAGED2 | c.1179G>A p.E393= | Silent (SNP) | VAF 37/209 reads (18%) | catalogued as COSV99514712; called by muse, mutect2, varscan2
- MGAM | c.1950C>T p.G650= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV101527693; called by muse, mutect2
- MICALL2 | c.1215C>T p.A405= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs1430092454, COSV99876194; called by muse, mutect2, varscan2
- MRPL57 | c.213C>T p.F71= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100006474; called by muse, mutect2, varscan2
- MUC16 | c.26715G>C p.V8905= | Silent (SNP) | VAF 59/248 reads (24%) | catalogued as COSV101200848; called by muse, mutect2, varscan2
- MUC16 | c.10584G>T p.L3528= | Silent (SNP) | VAF 52/219 reads (24%) | catalogued as COSV101200851; called by muse, mutect2, varscan2
- MYCBP2 | c.10182A>T p.I3394= (on ENST00000357337; = p.I3432= on NM_015057.5) | Silent (SNP) | VAF 81/293 reads (28%) | catalogued as COSV100631378; called by muse, mutect2, varscan2
- NEDD4L | c.1494C>T p.F498= (on ENST00000400345 / NM_001144967.3; = p.F478= on NM_015277.6) | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as COSV99896174; called by muse, mutect2, varscan2
- NEO1 | c.3102A>T p.A1034= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as COSV99982604; called by muse, mutect2
- NID1 | c.987C>T p.P329= | Silent (SNP) | VAF 45/202 reads (22%) | catalogued as COSV51621162, COSV99938075; called by muse, mutect2, varscan2
- NOTCH3 | c.5091G>T p.V1697= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99658438; called by muse, mutect2, varscan2
- NPY4R | c.186G>A p.L62= | Silent (SNP) | VAF 24/196 reads (12%) | catalogued as COSV100966201; called by muse, mutect2, varscan2
- ONECUT1 | c.1071G>T p.P357= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV100009383; called by muse, mutect2, varscan2
- OPALIN | c.351C>T p.D117= | Silent (SNP) | VAF 32/400 reads (8%) | catalogued as COSV100959650; called by muse, mutect2
- OR10G4 | c.247T>C p.L83= | Silent (SNP) | VAF 53/277 reads (19%) | catalogued as COSV100304935; called by muse, varscan2
- OR14C36 | c.894C>A p.A298= | Silent (SNP) | VAF 44/265 reads (17%) | catalogued as COSV100507615, COSV58601159; called by muse, mutect2, varscan2
- OR2AK2 | c.249C>A p.V83= | Silent (SNP) | VAF 84/389 reads (22%) | catalogued as COSV100824252; called by muse, mutect2, varscan2
- OR2T4 | c.261C>A p.L87= | Silent (SNP) | VAF 48/872 reads (6%) | catalogued as rs34261040, COSV100822570; called by muse, mutect2
- OR3A3 | c.492C>T p.N164= | Silent (SNP) | VAF 57/232 reads (25%) | catalogued as rs1354761038, COSV99351494; called by muse, mutect2, varscan2
- OR52K1 | c.627G>A p.V209= | Silent (SNP) | VAF 118/451 reads (26%) | catalogued as rs1387157755, COSV100297711, COSV56905080; called by muse, mutect2, varscan2
- OTOP1 | c.1197G>T p.S399= | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as COSV99587969; called by muse, mutect2, varscan2
- P2RY8 | c.552C>A p.L184= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV101184151, COSV67177371; called by muse, mutect2
- PAM | c.2199A>C p.A733= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV99173718; called by muse, mutect2, varscan2
- PARP16 | c.501G>C p.L167= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as COSV99975622; called by muse, mutect2, varscan2
- PCDH7 | c.2358A>G p.G786= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV100688565; called by muse, mutect2, varscan2
- PCDHA10 | c.324C>T p.I108= | Silent (SNP) | VAF 78/189 reads (41%) | catalogued as COSV56554934; called by muse, mutect2, varscan2
- PDE1C | c.810C>T p.Y270= | Silent (SNP) | VAF 19/225 reads (8%) | catalogued as rs375192379, COSV100370815; called by muse, mutect2
- PIGR | c.999G>T p.L333= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100732592; called by muse, mutect2, varscan2
- PLA2G2F | c.174G>A p.L58= | Silent (SNP) | VAF 35/143 reads (24%) | catalogued as COSV100907925; called by muse, mutect2, varscan2
- PLXNA2 | c.1911G>A p.L637= | Silent (SNP) | VAF 112/528 reads (21%) | catalogued as COSV100885668, COSV65443099; called by muse, mutect2, varscan2
- POLK | c.1758A>G p.E586= | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as COSV54033660; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.792G>T p.R264= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99461683; called by muse, mutect2, varscan2
- PPY | c.135G>A p.Q45= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as COSV56823438, COSV56823890; called by muse, mutect2, varscan2
- PRDM1 | c.2202C>T p.D734= | Silent (SNP) | VAF 49/377 reads (13%) | catalogued as COSV100958946; called by muse, mutect2, varscan2
- PRLR | c.1449T>C p.H483= | Silent (SNP) | VAF 49/278 reads (18%) | catalogued as COSV99184688; called by muse, mutect2, varscan2
- PROM2 | c.2025C>T p.P675= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV100469303; called by muse, mutect2, varscan2
- PXDN | c.2124G>T p.L708= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV99414542; called by muse, mutect2, varscan2
- RANBP3L | c.168C>T p.T56= | Silent (SNP) | VAF 80/432 reads (19%) | catalogued as COSV99683995; called by muse, mutect2, varscan2
- RASAL1 | c.1551C>G p.G517= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV99922026; called by muse, mutect2, varscan2
- RGS7 | c.975G>A p.Q325= | Silent (SNP) | VAF 52/243 reads (21%) | catalogued as COSV58535504; called by muse, varscan2
- RORB | c.852G>T p.V284= (on ENST00000396204 / NM_001365023.1; = p.V273= on NM_006914.4) | Silent (SNP) | VAF 61/224 reads (27%) | catalogued as COSV100974441, COSV65339336; called by muse, mutect2, varscan2
- ROS1 | c.4818T>A p.T1606= | Silent (SNP) | VAF 19/217 reads (9%) | catalogued as COSV100877565; called by muse, mutect2
- RXRG | c.282C>A p.A94= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV100717759; called by muse, mutect2, varscan2
- SLC30A8 | c.93G>A p.P31= | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as rs751667454, COSV69968152, COSV69973921; called by muse, mutect2, varscan2
- SLC7A14 | c.363C>G p.T121= | Silent (SNP) | VAF 17/137 reads (12%) | catalogued as COSV99200818; called by muse, mutect2, varscan2
- SLCO5A1 | c.372C>G p.L124= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV99480724; called by muse, mutect2, varscan2
- SLIT1 | c.2571C>G p.S857= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99822226; called by muse, mutect2, varscan2
- SSX3 | c.429A>G p.G143= | Silent (SNP) | VAF 60/450 reads (13%) | catalogued as COSV100035436; called by muse, mutect2, varscan2
- SV2B | c.864C>G p.T288= | Silent (SNP) | VAF 47/160 reads (29%) | catalogued as COSV100370865, COSV57701658; called by muse, mutect2, varscan2
- TBC1D2 | c.2020C>T p.L674= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs1421288192, COSV100580107; called by muse, mutect2, varscan2
- TBC1D3I | c.321G>A p.R107= | Silent (SNP) | VAF 90/254 reads (35%) | called by muse, mutect2, varscan2
- TBX4 | c.948G>A p.P316= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs765251401, COSV53610352; called by muse, mutect2, varscan2
- TEKT4 | c.54C>A p.A18= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99726626; called by muse, mutect2, varscan2
- THOC1 | c.1047A>G p.Q349= | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as rs1249681716, COSV99863558; called by muse, mutect2, varscan2
- TMEM44 | c.957G>A p.K319= (on ENST00000392432 / NM_001166305.2; = p.K272= on NM_138399.5) | Silent (SNP) | VAF 91/650 reads (14%) | catalogued as rs771233810, COSV99861949; called by muse, mutect2, varscan2
- TMEM8B | c.186C>T p.A62= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100941698; called by muse, mutect2, varscan2
- TNN | c.1737G>T p.G579= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as COSV99512699; called by muse, varscan2
- TRAV22 | c.15G>A p.L5= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- TRAV8-7 | c.15C>A p.V5= | Silent (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- TRIM60 | c.366C>T p.S122= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV100594088; called by muse, mutect2, varscan2
- TRPA1 | c.2592G>A p.E864= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs769931136, COSV100084901, COSV51567133; called by muse, mutect2
- TRPC3 | c.909C>A p.S303= (on ENST00000379645 / NM_001366479.2; = p.S230= on NM_003305.2) | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV99313299; called by muse, mutect2
- TTI1 | c.2973C>A p.G991= | Silent (SNP) | VAF 35/324 reads (11%) | catalogued as COSV100989718, COSV100989825; called by muse, mutect2, varscan2
- TTN | c.15000G>A p.Q5000= (on ENST00000591111; = p.Q4073= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/200 reads (24%) | catalogued as rs1376351122, COSV100624735; called by muse, varscan2
- TXLNB | c.531T>C p.R177= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as COSV100625127; called by muse, mutect2, varscan2
- VIRMA | c.783G>A p.E261= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV99889090; called by muse, mutect2, varscan2
- VSTM2A | c.345C>T p.S115= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV56496034; called by muse, mutect2, varscan2
- WDR7 | c.51G>T p.A17= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as rs749728680, COSV99590151; called by muse, mutect2
- ZNF239 | c.924C>A p.I308= | Silent (SNP) | VAF 32/200 reads (16%) | catalogued as rs754438172, COSV100021871; called by muse, mutect2, varscan2
- ZNF774 | c.654C>T p.D218= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as COSV100586442; called by muse, mutect2
- ZNF804A | c.1599C>A p.S533= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as COSV100169562, COSV56450521; called by muse, mutect2, varscan2
- AP2A2 | c.*684G>T | 3'UTR (SNP) | VAF 24/67 reads (36%) | catalogued as rs778049917, COSV100173238; called by muse, mutect2, varscan2
- ATE1 | c.942+1014G>T | Intron (SNP) | VAF 44/177 reads (25%) | catalogued as COSV99817553; called by muse, mutect2, varscan2
- BTN2A3P | n.1567A>T | RNA (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- C14orf177 | n.563G>T | RNA (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100362729; called by muse, mutect2, varscan2
- CHRM2 | c.-47+33869C>A | Intron (SNP) | VAF 27/157 reads (17%) | catalogued as COSV100280814, COSV100281709; called by muse, mutect2, varscan2
- COG5 | c.-13G>T | 5'UTR (SNP) | VAF 16/46 reads (35%) | catalogued as rs915925086, COSV99709264; called by muse, mutect2, varscan2
- CTSL3P | n.190G>T | RNA (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- CTSL3P | n.191G>T | RNA (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- DCHS2 | n.1470C>A | RNA (SNP) | VAF 20/127 reads (16%) | catalogued as COSV100252783; called by muse, mutect2, varscan2
- HRAS | c.450+137del | Intron (DEL) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- KLC4 | c.-26+551C>T | Intron (SNP) | VAF 31/152 reads (20%) | catalogued as COSV99432436; called by muse, mutect2, varscan2
- MASP1 | c.1303+5686C>A | Intron (SNP) | VAF 23/156 reads (15%) | catalogued as rs745444812, COSV56221819, COSV99962704; called by muse, mutect2, varscan2
- RBPMS2 | c.88-10751G>T | Intron (SNP) | VAF 37/189 reads (20%) | catalogued as rs1297255275, COSV100264951; called by muse, mutect2, varscan2
- SLC30A2 | c.271+685G>T | Intron (SNP) | VAF 14/76 reads (18%) | catalogued as COSV100958614; called by muse, mutect2, varscan2
- SSPOP | n.14379T>C | RNA (SNP) | VAF 20/169 reads (12%) | catalogued as COSV100947872; called by muse, mutect2, varscan2
- ST20-MTHFS | c.-12+463A>T | Intron (SNP) | VAF 7/63 reads (11%) | catalogued as COSV101530535; called by muse, mutect2, varscan2
- TTN | c.10361-3705T>C | Intron (SNP) | VAF 23/196 reads (12%) | catalogued as COSV100624738; called by muse, mutect2, varscan2
- UGGT2 | c.1031+1028A>T | Intron (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100942632; called by muse, mutect2, varscan2
